Somatic mutation profile of tumor specimen TCGA-BF-A1PV-01A (aliquot TCGA-BF-A1PV-01A-11D-A19A-08) from TCGA case TCGA-BF-A1PV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 74.3 years (27,124 days).
Specimen TCGA-BF-A1PV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b93418ee-b1bb-4853-a1f1-200523792c15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A1PV-10A (Blood Derived Normal), aliquot TCGA-BF-A1PV-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c083b72d-97af-45ba-98ad-664f066a8a14

The open-access MAF lists 333 somatic variants for this specimen: 229 protein-altering or splice-affecting, 91 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 91, Nonsense Mutation 7, Intron 6, 3'UTR 2, RNA 2, 5'Flank 2, Splice Site 2, Splice Region 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.1921T>A p.Y641N (on ENST00000460911 / NM_001203247.2; = p.Y646N on NM_004456.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs267601395, COSV57445793, COSV57445823, COSV57462051; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 40/44 reads (91%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 61/137 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.377); catalogued as COSV60198634; called by muse, mutect2, varscan2
- ABCC9 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV53987421; called by muse, mutect2, varscan2
- AC008397.2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1268523791, COSV53206271; called by muse, mutect2, varscan2
- ACCSL | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs1444024563, COSV66580861; called by muse, mutect2, varscan2
- ACE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 127/144 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs371544905, COSV99327658; called by muse, mutect2, varscan2
- ACSM5 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59370619; called by muse, mutect2, varscan2
- ADAM21 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV50790952; called by muse, mutect2, varscan2
- ADAM23 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1274707603, COSV52211960; called by muse, mutect2, varscan2
- ADAMTS13 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100747040, COSV63020881; called by muse, mutect2
- ADGRF2 | c.1786C>T p.L596F (on ENST00000296862 / NM_001368115.2; = p.L528F on NM_153839.7) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57287669; called by muse, mutect2, varscan2
- ADGRG4 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs143735478, COSV54953456; called by muse, mutect2, varscan2
- ADGRG7 | c.2380A>G p.K794E | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV56295362; called by muse, mutect2, varscan2
- AHNAK | c.343-2A>G p.X115_splice | Splice Site (SNP) | VAF 22/34 reads (65%) | catalogued as COSV99945794; called by muse, mutect2, varscan2
- AIRE | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as rs753097871, COSV52393515; called by muse, mutect2, varscan2
- AKAP13 | c.6463G>A p.V2155I (on ENST00000394518 / NM_007200.5; = p.V2159I on NM_006738.6) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63453519; called by muse, mutect2, varscan2
- AKAP6 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55210392; called by muse, mutect2, varscan2
- ARHGEF10 | c.2195C>T p.A732V (on ENST00000398564; = p.A707V on NM_014629.4) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs1229943246, COSV50645762; called by muse, mutect2, varscan2
- ARPP21 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51795289; called by muse, mutect2, varscan2
- ASS1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV61688970; called by muse, mutect2, varscan2
- AVPR2 | c.24C>T p.S8= | Splice Region (SNP) | VAF 44/122 reads (36%) | catalogued as rs201419746, COSV61686024; called by muse, mutect2, varscan2
- BCL11A | c.746G>A p.G249E (on ENST00000335712 / NM_001365609.1; = p.G283E on NM_018014.4) | Missense Mutation (SNP) | VAF 260/627 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.118); catalogued as COSV59627781; called by muse, mutect2, varscan2
- BCORL1 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV54393760; called by muse, mutect2, varscan2
- BOP1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1427930197; called by muse, mutect2, varscan2
- BPIFC | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV55911788; called by muse, mutect2, varscan2
- BRCA2 | c.6200C>T p.S2067F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV66451865; called by muse, mutect2, varscan2
- BRD1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164193595, COSV53456242; called by muse, mutect2, varscan2
- BRINP2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64176839; called by muse, mutect2
- BTBD11 | c.2096G>A p.G699E (on ENST00000280758 / NM_001018072.2; = p.G236E on NM_001017523.2) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603282, COSV55021617; called by muse, mutect2, varscan2
- BTBD16 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV53262020; called by muse, mutect2, varscan2
- BTK | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as COSV58118689; called by muse, mutect2, varscan2
- BUB1 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57062570; called by muse, mutect2, varscan2
- C12orf50 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV53894520, COSV53897632; called by muse, mutect2, varscan2
- C3orf20 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV53784274; called by muse, mutect2, varscan2
- CACNA1I | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60803623; called by muse, mutect2, varscan2
- CCDC138 | c.1734A>T p.L578F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.08); catalogued as COSV54566143; called by muse, mutect2
- CDC42BPB | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100775484, COSV63474627; called by muse, mutect2, varscan2
- CEL | c.278C>T p.T93I (on ENST00000673714; = p.T90I on NM_001807.6) | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV60826817; called by muse, mutect2, varscan2
- CELF4 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs780184425, COSV58450939; called by muse, mutect2, varscan2
- CEP350 | c.5455C>T p.P1819S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV62603115; called by muse, mutect2, varscan2
- CEP350 | c.5456C>T p.P1819L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV100854334; called by muse, mutect2, varscan2
- CFAP206 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51533423; called by muse, mutect2, varscan2
- CFAP47 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.085); catalogued as COSV52883070; called by muse, mutect2, varscan2
- COBLL1 | c.590C>T p.T197I (on ENST00000392717; = p.T159I on NM_014900.5) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52065975; called by muse, mutect2, varscan2
- COL11A1 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV62173347; called by muse, mutect2, varscan2
- COL11A1 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62173003; called by muse, mutect2, varscan2
- COL4A2 | c.4216C>T p.P1406S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as rs1452839928, COSV64627026; called by muse, mutect2, varscan2
- COL6A3 | c.8063C>T p.S2688F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55085830; called by muse, mutect2, varscan2
- CRX | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV55757757; called by muse, mutect2, varscan2
- CSMD1 | c.10303G>A p.G3435R (on ENST00000520002; = p.G3434R on NM_033225.6) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1407187951, COSV100144372; called by muse, mutect2, varscan2
- CSMD3 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as rs763316092, COSV52149077; called by muse, mutect2, varscan2
- CTAGE1 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66943003, COSV66943270, COSV66943765; called by muse, mutect2, varscan2
- CTNNA2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.227); catalogued as rs1216702402, COSV63552128; called by muse, mutect2, varscan2
- CTNND2 | c.2147C>T p.T716I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100472364; called by muse, mutect2, varscan2
- CTTNBP2 | c.2011G>A p.V671I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs755763104, COSV50395051; called by muse, mutect2, varscan2
- CXCR2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV59280351; called by muse, mutect2, varscan2
- CYP2J2 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV64605876; called by muse, mutect2, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DDX39B | c.825C>G p.N275K | Missense Mutation (SNP) | VAF 70/111 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV100795174, COSV63331267; called by muse, mutect2, varscan2
- DEFB125 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV66703202; called by muse, mutect2, varscan2
- DLEC1 | c.3995G>A p.G1332D | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV57297979; called by muse, mutect2, varscan2
- DMRT3 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 30/51 reads (59%) | catalogued as rs374319022, COSV51907430; called by muse, mutect2, varscan2
- DPEP1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs762668222, COSV55359766; called by muse, mutect2, varscan2
- DPPA2 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV72118005; called by muse, mutect2, varscan2
- DRD2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60756659; called by muse, mutect2, varscan2
- DSP | c.6834G>A p.M2278I | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV65792245, COSV65794785; called by muse, mutect2, varscan2
- DTNA | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs781374642, COSV51998351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFHB | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.025); catalogued as COSV55546838; called by muse, mutect2, varscan2
- ENPEP | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV54449193; called by muse, mutect2, varscan2
- EPHA1 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.977); catalogued as rs111858878, COSV51970291; called by muse, mutect2, varscan2
- ETAA1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as COSV55472623; called by muse, mutect2, varscan2
- F11 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53005890; called by muse, mutect2, varscan2
- FAM135B | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV52708436; called by muse, mutect2, varscan2
- FAM13A | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1393166051, COSV99982912; called by muse, mutect2, varscan2
- FAM221B | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV65074140; called by muse, mutect2, varscan2
- FAM71B | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV57228438; called by muse, mutect2, varscan2
- FARP2 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV99883977; called by muse, mutect2, varscan2
- FCN1 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV65662153; called by muse, mutect2, varscan2
- FER1L6 | c.4639C>T p.P1547S | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67549052; called by muse, mutect2, varscan2
- FMO1 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV61445272; called by muse, mutect2, varscan2
- FOXN1 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56881320; called by muse, mutect2, varscan2
- FRMD3 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV58459306; called by muse, mutect2, varscan2
- FRMPD4 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV66213372; called by muse, mutect2, varscan2
- FYB2 | c.1847A>C p.K616T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV58584027; called by muse, mutect2, varscan2
- GALC | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV54324553; called by muse, mutect2, varscan2
- GALNT13 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101224395, COSV67216396; called by muse, mutect2, varscan2
- GALNT15 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60215474; called by muse, mutect2, varscan2
- GCNT3 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV68532146; called by muse, mutect2, varscan2
- GGT6 | c.1187G>A p.S396N (on ENST00000574154 / NM_001122890.3; = p.S364N on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV54596368; called by muse, mutect2, varscan2
- GPC3 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV63662165; called by muse, mutect2, varscan2
- GPRIN2 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100966304; called by muse, mutect2, varscan2
- GPRIN2 | c.1083T>G p.H361Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100966302; called by muse, mutect2, varscan2
- GRID1 | c.1637A>G p.K546R | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60022728; called by muse, mutect2, varscan2
- GSX2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV58842691; called by muse, mutect2, varscan2
- HDC | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as COSV51069250; called by muse, mutect2
- HERPUD1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398907374, COSV55861893; called by muse, mutect2, varscan2
- HNRNPR | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs756640713, COSV56420891; called by muse, mutect2, varscan2
- HROB | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 92/99 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55369278; called by muse, mutect2, varscan2
- HTR3E | c.1102G>A p.E368K (on ENST00000415389 / NM_001256613.1; = p.E383K on NM_182589.2) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0.047); catalogued as COSV58945796; called by muse, mutect2, varscan2
- HUWE1 | c.4964G>A p.R1655Q | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782782151, COSV53341705; called by muse, mutect2, varscan2
- HYDIN | c.9269G>A p.G3090E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.124); catalogued as COSV59254430; called by muse, mutect2, varscan2
- IFRD2 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.621); catalogued as COSV57113271; called by muse, mutect2, varscan2
- IGF2R | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63628130; called by muse, mutect2, varscan2
- IGHV3-43 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1567498444; called by muse, mutect2, varscan2
- IRF3 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0.115); catalogued as COSV55862852; called by muse, mutect2, varscan2
- KALRN | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53759898; called by muse, mutect2, varscan2
- KCNA5 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV52904045; called by muse, mutect2, varscan2
- KCNA6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs866418364, COSV54974491; called by muse, mutect2, varscan2
- KCND3 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as COSV56178563; called by muse, mutect2, varscan2
- KCNJ3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867432352, COSV54534617, COSV54538785; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KIAA1109 | c.13931C>T p.P4644L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1488609966, COSV52668432; called by muse, mutect2, varscan2
- KRT75 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV52871472; called by muse, mutect2, varscan2
- KRTAP10-10 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59955144; called by muse, mutect2, varscan2
- KRTAP5-6 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); catalogued as COSV66289179; called by muse, mutect2, varscan2
- L1TD1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV63133371; called by mutect2, varscan2
- LGALS3BP | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 68/78 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99431386; called by muse, mutect2
- LILRA2 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV52196350; called by muse, mutect2
- LMCD1 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs200525976, COSV50087799; called by muse, mutect2, varscan2
- LRP1B | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67204342; called by muse, mutect2, varscan2
- LRRN2 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.336); catalogued as COSV65783514; called by muse, mutect2, varscan2
- LZTR1 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs368589786; called by muse, mutect2, varscan2
- MAGEE2 | c.845C>A p.P282Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV64897547, COSV64898631; called by muse, mutect2, varscan2
- MAMDC2 | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV65857555; called by muse, mutect2, varscan2
- MTBP | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1417089013, COSV100011851; called by muse, mutect2, varscan2
- MTBP | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100011852; called by muse, mutect2, varscan2
- MTM1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as CD133052, COSV60334525; called by mutect2, varscan2
- MUC16 | c.34060C>T p.P11354S | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.133); catalogued as COSV67458445; called by muse, mutect2, varscan2
- MUC16 | c.11545A>G p.T3849A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs1160936980, COSV67458454; called by muse, mutect2, varscan2
- MUC17 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV60285426; called by muse, mutect2, varscan2
- MYCN | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55258316; called by muse, mutect2, varscan2
- MYPN | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288217143, COSV62732878; called by muse, mutect2, varscan2
- NEBL | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65802004; called by muse, mutect2, varscan2
- NEUROD6 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as COSV51770988, COSV99774247; called by muse, mutect2, varscan2
- NIN | c.6025C>T p.Q2009* (on ENST00000382041 / NM_182946.1; = p.Q1296* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55386409; called by muse, mutect2, varscan2
- NKD2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs143957338; called by muse, mutect2, varscan2
- NLRC5 | c.5539C>T p.Q1847* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV52648562, COSV52657293; called by muse, mutect2, varscan2
- NME9 | c.838G>A p.G280R (on ENST00000333911 / NM_001349024.2; = p.G219R on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58617816; called by muse, mutect2, varscan2
- NOMO2 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs550469735, COSV57916304; called by muse, mutect2, varscan2
- NPBWR2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769499233, COSV63899983; called by muse, mutect2, varscan2
- NRAP | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as rs373402154; called by muse, varscan2
- OASL | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 220/500 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs765299664, COSV57477889; called by muse, mutect2, varscan2
- OGN | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52760673; called by muse, mutect2, varscan2
- OR13C9 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52241437; called by muse, mutect2, varscan2
- OR14K1 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99314970; called by muse, mutect2
- OR1S1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1406919672, COSV100515353, COSV58706707; called by muse, mutect2, varscan2
- OR2T3 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs552029313, COSV100613474, COSV62081866; called by muse, mutect2, varscan2
- OR52M1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1442619258, COSV64171469; called by muse, mutect2, varscan2
- OR5M3 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV56566381; called by muse, mutect2
- OR6N1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV100625084, COSV58647929; called by muse, mutect2, varscan2
- OSMR | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57083671; called by muse, mutect2, varscan2
- PADI6 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553893773, COSV61884194; called by muse, mutect2, varscan2
- PASK | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52151055; called by muse, mutect2, varscan2
- PCDHA12 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.07); catalogued as COSV56480390; called by muse, mutect2, varscan2
- PCDHB1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV60630265; called by muse, mutect2, varscan2
- PGAP2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs181958368, COSV53464768; called by muse, mutect2, varscan2
- PIP5K1B | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs138893749; called by muse, mutect2, varscan2
- PLEKHA4 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1035735985, COSV54362362, COSV54363421; called by muse, mutect2, varscan2
- PLEKHA7 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs994546822, COSV60580215; called by muse, mutect2, varscan2
- PON1 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763855506, COSV55931378; called by muse, mutect2, varscan2
- POTEF | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as rs373993925, COSV99051460; called by muse, mutect2, varscan2
- PPP1CA | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as rs1273880415, COSV56702423; called by muse, mutect2, varscan2
- PRDM13 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV65029429; called by muse, mutect2, varscan2
- PRSS58 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs146814209, COSV101616130; called by muse, mutect2, varscan2
- PRUNE2 | c.5926C>T p.H1976Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs769064621, COSV65040240; called by muse, mutect2, varscan2
- PSG6 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV51831909; called by muse, mutect2, varscan2
- PWP1 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV69832626; called by muse, mutect2, varscan2
- PXDNL | c.3410C>T p.S1137L | Missense Mutation (SNP) | VAF 187/280 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62484880; called by muse, mutect2, varscan2
- PZP | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54357898; called by muse, mutect2, varscan2
- RASGRP2 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100818237, COSV62449200; called by muse, mutect2, varscan2
- RCBTB1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV51634026; called by muse, mutect2, varscan2
- REV1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV51483781; called by muse, mutect2, varscan2
- RNF123 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57538154; called by muse, mutect2, varscan2
- RNF148 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV57357950; called by muse, mutect2, varscan2
- SAMD7 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59417153, COSV59418053; called by muse, mutect2, varscan2
- SBF1 | c.3334C>T p.P1112S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs183944303; called by muse, mutect2, varscan2
- SERPINA11 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV58241554; called by muse, mutect2, varscan2
- SETBP1 | c.4171+1G>A p.X1391_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56318431; called by muse, mutect2, varscan2
- SIPA1L2 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs571522347, COSV53388044; called by muse, mutect2, varscan2
- SLC10A2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370357133, COSV55357044; called by muse, mutect2, varscan2
- SLC19A1 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1569003098, COSV60754024; called by muse, mutect2
- SLC37A3 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV58264102; called by muse, mutect2, varscan2
- SLC39A5 | c.116A>C p.Y39S | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57191321; called by muse, mutect2, varscan2
- SLC44A1 | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1241695937, COSV58263696; called by muse, mutect2, varscan2
- SLC6A18 | c.946A>G p.T316A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV57250542; called by muse, mutect2, varscan2
- SLCO1C1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV56870975, COSV99858720; called by muse, mutect2, varscan2
- SNRNP200 | c.4795C>T p.P1599S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60488986; called by muse, mutect2, varscan2
- SORBS2 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52996293; called by muse, mutect2, varscan2
- SORT1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV56665442; called by muse, varscan2
- SPANXN2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 62/144 reads (43%) | catalogued as COSV65128157; called by muse, varscan2
- SPATA2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56866264; called by muse, mutect2, varscan2
- SPTA1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV63753714; called by muse, varscan2
- SPTBN4 | c.6049G>A p.D2017N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV58946955; called by muse, varscan2
- SRRT | c.1697T>A p.I566N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV53816656; called by muse, mutect2
- SS18 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52260515; called by muse, mutect2
- STAB2 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV66337431, COSV66340122; called by muse, mutect2, varscan2
- STRA6 | c.720G>A p.K240= | Splice Region (SNP) | VAF 67/130 reads (52%) | catalogued as COSV60585500; called by muse, mutect2, varscan2
- SVEP1 | c.7568C>T p.S2523F | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52838003, COSV99928976; called by muse, mutect2, varscan2
- SYNJ1 | c.3310C>T p.P1104S | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs759699908, COSV59146725; called by muse, mutect2, varscan2
- SYT1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54041684; called by muse, mutect2, varscan2
- SYT9 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59616419; called by muse, mutect2, varscan2
- TAF1L | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749284231, COSV54256396; called by muse, mutect2, varscan2
- TCEAL4 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as COSV65463196; called by muse, mutect2, varscan2
- THOC2 | c.4442G>A p.R1481Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55543980, COSV99834326; called by muse, mutect2, varscan2
- THSD7B | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55673199; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TMC5 | c.1688G>A p.G563E (on ENST00000396229 / NM_001105248.1; = p.G317E on NM_024780.5) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.118); catalogued as rs1163748944, COSV54902942; called by muse, mutect2, varscan2
- TTC7A | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55413895; called by muse, mutect2, varscan2
- TTN | c.7145A>C p.E2382A (on ENST00000591111; = p.E2336A on NM_003319.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | PolyPhen possibly damaging (0.84); catalogued as COSV59983183; called by muse, mutect2, varscan2
- TXLNA | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs376946008; called by muse, mutect2, varscan2
- UGT3A2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV56929765; called by muse, mutect2, varscan2
- USH2A | c.14887G>A p.E4963K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56353758; called by muse, mutect2, varscan2
- USP54 | c.4978G>A p.G1660R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV100357049; called by muse, mutect2, varscan2
- VAV2 | c.679C>T p.P227S (on ENST00000371850 / NM_001134398.2; = p.P222S on NM_003371.4) | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs760535339, COSV64081252; called by muse, mutect2, varscan2
- VPS13A | c.8606C>T p.P2869L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867999286, COSV62427710; called by muse, varscan2
- WFDC12 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65660949; called by muse, mutect2, varscan2
- XDH | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052025; called by muse, mutect2, varscan2
- XDH | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052027; called by muse, varscan2
- YAP1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56773684; called by muse, mutect2, varscan2
- ZMIZ2 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV54806115; called by muse, mutect2, varscan2
- ZNF445 | c.1705C>T p.L569F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV68538733; called by muse, mutect2, varscan2
- ZNF765 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV67182252; called by muse, mutect2, varscan2
- ZNF804A | c.2545A>G p.I849V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56443387; called by muse, mutect2, varscan2
- ANXA8 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IGHV4-61 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, varscan2
- PRAMEF17 | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ZFX | c.768dup p.K257* | Frame Shift Ins (INS) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- ABCC11 | c.2241G>A p.K747= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV62322466, COSV62326526; called by muse, mutect2, varscan2
- ABCC11 | c.327G>A p.R109= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV62322471, COSV62325469; called by muse, mutect2, varscan2
- ABCC6 | c.1038C>T p.A346= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs764622792, COSV99227907, COSV99228122; called by muse, mutect2, varscan2
- AC126283.2 | c.627C>T p.F209= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs868123583, COSV67098265; called by muse, mutect2, varscan2
- ADD1 | c.960C>T p.N320= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV53268017; called by muse, mutect2, varscan2
- ADGRG4 | c.1677C>T p.F559= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV54953445, COSV99794818; called by muse, mutect2, varscan2
- AFM | c.684G>A p.L228= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56919705; called by muse, mutect2, varscan2
- AMER1 | c.2632C>T p.L878= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57658604; called by muse, mutect2, varscan2
- AQP3 | c.663C>T p.G221= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53048141; called by muse, mutect2, varscan2
- ARID5B | c.408G>A p.R136= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV54417811; called by muse, mutect2, varscan2
- CACNA1A | c.1530C>T p.N510= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100801838, COSV64194992; called by muse, mutect2, varscan2
- CACNA1I | c.147C>T p.V49= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs927246491, COSV60805201; called by muse, mutect2, varscan2
- CAMSAP2 | c.3333C>T p.P1111= (on ENST00000236925 / NM_001297707.2; = p.P1100= on NM_203459.3) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs141562761, COSV52668640; called by muse, mutect2, varscan2
- CHD7 | c.297G>C p.A99= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV71108924; called by muse, mutect2, varscan2
- CHI3L1 | c.867G>A p.K289= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1158233116, COSV55137704; called by muse, mutect2, varscan2
- CHST1 | c.1161C>T p.I387= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs985096921, COSV57323051; called by muse, mutect2, varscan2
- COL14A1 | c.5280C>T p.D1760= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV52851346; called by muse, mutect2, varscan2
- CSMD1 | c.546C>T p.I182= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV101225334, COSV68190600; called by muse, mutect2, varscan2
- CSMD2 | c.8517G>A p.G2839= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV53900551; called by muse, mutect2, varscan2
- CYP1A2 | c.1521C>T p.V507= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV59659495; called by muse, mutect2, varscan2
- CYP2B6 | c.507C>T p.F169= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV57842723, COSV57843227; called by mutect2, varscan2
- DEF6 | c.897G>A p.Q299= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV57353714; called by muse, mutect2
- DLG5 | c.4524C>T p.S1508= | Silent (SNP) | VAF 74/219 reads (34%) | catalogued as COSV64947532, COSV64950410; called by muse, mutect2, varscan2
- DUSP22 | c.300C>T p.I100= | Silent (SNP) | VAF 67/436 reads (15%) | catalogued as rs746498411, COSV60524166, COSV60525568, COSV60528378; called by muse, mutect2, varscan2
- EDEM3 | c.2577C>T p.S859= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs770699770, COSV58923439; called by muse, mutect2, varscan2
- EPHB2 | c.1371C>T p.S457= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV65861548; called by muse, mutect2, varscan2
- FAM13A | c.2583G>A p.R861= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52004369; called by muse, mutect2, varscan2
- FAM234A | c.1536C>T p.I512= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs189557540, COSV51451398; called by muse, mutect2, varscan2
- FILIP1L | c.2307G>A p.K769= (on ENST00000354552 / NM_182909.3; = p.K529= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV58767129; called by muse, mutect2, varscan2
- FLNA | c.792C>T p.F264= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV61040997; called by muse, mutect2, varscan2
- FLYWCH1 | c.1290C>T p.F430= (on ENST00000253928 / NM_001308068.2; = p.F429= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1160895901, COSV54144347; called by muse, mutect2
- GALNT8 | c.741G>A p.L247= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99362513; called by mutect2, varscan2
- GARS1 | c.1752C>T p.I584= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV66828145; called by muse, mutect2, varscan2
- GLIS3 | c.165G>A p.T55= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs143229220; called by muse, mutect2, varscan2
- GPLD1 | c.1794G>A p.G598= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV57755951; called by muse, mutect2, varscan2
- HYDIN | c.9270G>A p.G3090= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99992046; called by muse, mutect2, varscan2
- IQCN | c.1776C>T p.V592= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1568279587, COSV66573475; called by muse, mutect2, varscan2
- IQSEC3 | c.1039C>T p.L347= (on ENST00000538872 / NM_001170738.2; = p.L44= on NM_015232.1) | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV58283319; called by muse, mutect2, varscan2
- ITGAX | c.1716C>T p.I572= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs202220518; called by muse, varscan2
- LGALS12 | c.921C>T p.V307= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV55369907; called by muse, mutect2, varscan2
- LGALS3BP | c.750C>T p.L250= | Silent (SNP) | VAF 61/71 reads (86%) | catalogued as rs992118941, COSV99431391; called by muse, mutect2, varscan2
- LGALS9C | c.450C>T p.P150= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV60195413; called by mutect2, varscan2
- LRRIQ1 | c.2286G>A p.K762= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV67828859; called by muse, mutect2, varscan2
- LY86 | c.27C>T p.F9= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as COSV57911574; called by muse, mutect2, varscan2
- MCC | c.1254C>T p.T418= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs202164331, COSV56727210; called by muse, mutect2, varscan2
- MTCL1 | c.2703C>T p.S901= (on ENST00000306329 / NM_001378206.1; = p.S541= on NM_015210.4) | Silent (SNP) | VAF 105/162 reads (65%) | catalogued as rs763342113, COSV60405116; called by muse, mutect2, varscan2
- MTMR7 | c.1443G>A p.Q481= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV51664908; called by muse, mutect2, varscan2
- NBEA | c.8106C>T p.F2702= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV59774584; called by muse, mutect2, varscan2
- NEXMIF | c.4143C>T p.I1381= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV50026508; called by muse, mutect2, varscan2
- NLGN4X | c.1755G>A p.T585= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as rs1223422972, COSV52008650; called by muse, mutect2, varscan2
- NLRP10 | c.270C>T p.L90= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV60779776; called by muse, mutect2, varscan2
- NLRP3 | c.2650C>T p.L884= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV60222509; called by muse, mutect2, varscan2
- NPC1L1 | c.2475G>A p.E825= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV56923997; called by muse, mutect2, varscan2
- NUP155 | c.1854C>T p.S618= (on ENST00000231498 / NM_153485.3; = p.S559= on NM_004298.4) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV51528896, COSV99193375; called by muse, mutect2, varscan2
- OASL | c.594C>T p.F198= | Silent (SNP) | VAF 161/365 reads (44%) | catalogued as rs759301773, COSV57477529; called by muse, mutect2, varscan2
- OR11G2 | c.1020G>A p.K340= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as COSV62132082; called by muse, mutect2, varscan2
- OR5H2 | c.474C>T p.F158= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV62350523; called by muse, mutect2, varscan2
- PAFAH2 | c.840C>T p.I280= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV65339382; called by muse, mutect2, varscan2
- PARVB | c.159C>T p.L53= | Silent (SNP) | VAF 76/206 reads (37%) | catalogued as COSV63109663; called by muse, mutect2, varscan2
- PCARE | c.3828C>T p.S1276= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV59054237; called by muse, mutect2, varscan2
- PCSK5 | c.4941G>A p.G1647= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV70448792; called by muse, mutect2, varscan2
- PIGG | c.2229C>T p.F743= (on ENST00000453061 / NM_001127178.3; = p.F735= on NM_017733.4) | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV56317402; called by muse, mutect2, varscan2
- PLCG2 | c.3042C>T p.F1014= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs749739675, COSV63868649; called by muse, mutect2, varscan2
- PLCXD3 | c.519G>A p.A173= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2, varscan2
- PRAMEF2 | c.138G>A p.R46= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs764665499, COSV53574311; called by muse, mutect2, varscan2
- PRUNE2 | c.3207T>C p.D1069= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV65040243; called by muse, mutect2, varscan2
- PTCHD1 | c.948G>A p.G316= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV65059668; called by muse, mutect2, varscan2
- PTK6 | c.948G>A p.R316= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as COSV53916422; called by muse, mutect2, varscan2
- RANBP2 | c.5673C>T p.I1891= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs534500585, COSV51699170; called by muse, mutect2, varscan2
- RFPL1 | c.333G>A p.K111= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV62977682; called by muse, mutect2, varscan2
- RYR1 | c.14604G>A p.E4868= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV62094273; called by muse, mutect2, varscan2
- S100A7A | c.129C>T p.F43= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV61330316; called by muse, mutect2, varscan2
- SAMD12 | c.369G>A p.G123= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV59048080; called by muse, mutect2, varscan2
- SERPINA10 | c.420C>T p.L140= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV56227978; called by muse, mutect2, varscan2
- SERPINB2 | c.255C>T p.I85= | Silent (SNP) | VAF 58/86 reads (67%) | catalogued as COSV55091891; called by muse, mutect2, varscan2
- SLITRK1 | c.1329C>T p.F443= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV65675068; called by muse, mutect2, varscan2
- SPHKAP | c.609G>A p.T203= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1246576109, COSV60869524; called by muse, mutect2, varscan2
- SPN | c.375A>G p.L125= | Silent (SNP) | VAF 51/103 reads (50%) | catalogued as COSV64070152; called by muse, mutect2, varscan2
- SRRT | c.1695G>A p.L565= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs753149475, COSV53816650; called by muse, mutect2
- SVOPL | c.1101C>T p.F367= (on ENST00000419765; = p.F215= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV55989819; called by muse, mutect2, varscan2
- TENM3 | c.636G>A p.R212= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as COSV69304151; called by muse, mutect2, varscan2
- TLR2 | c.1234C>T p.L412= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52605782; called by muse, mutect2, varscan2
- TLR7 | c.2538C>T p.S846= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV66124032; called by muse, mutect2, varscan2
- TMEM26 | c.873G>A p.A291= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs199546375; called by muse, mutect2, varscan2
- TTC7A | c.1446C>T p.A482= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs955968971, COSV99766065; called by muse, mutect2, varscan2
- UBE4A | c.270G>A p.R90= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV52803588; called by muse, mutect2, varscan2
- UNC5CL | c.1041G>A p.R347= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV55109551; called by muse, mutect2
- USP54 | c.4977G>A p.E1659= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100357054; called by muse, mutect2, varscan2
- VARS1 | c.1695C>T p.I565= | Silent (SNP) | VAF 97/349 reads (28%) | catalogued as COSV63304437; called by muse, mutect2, varscan2
- VPS13B | c.3621C>T p.L1207= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs373889030, COSV100662603; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNRF4 | c.237C>T p.A79= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as COSV55773633; called by muse, mutect2, varscan2
- AC004223.3 | c.427-9974C>T | Intron (SNP) | VAF 20/21 reads (95%) | catalogued as rs763790280, COSV52071271; called by muse, mutect2, varscan2
- AC073310.1 | n.238C>T | RNA (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415329 C>T | 5'Flank (SNP) | VAF 37/133 reads (28%) | catalogued as COSV52567309; called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2790T>C | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs780922027, COSV99805515; called by muse, mutect2, varscan2
- ENTPD5 | chr14:73961534 C>G | 3'Flank (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53178421, COSV53178695; called by muse, mutect2, varscan2
- ITGB4 | c.4558+336C>T | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99563439; called by muse, mutect2, varscan2
- MIR124-2 | n.98G>A | RNA (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- NR1I3 | c.*33G>A | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100915512; called by muse, mutect2, varscan2
- PCDHGA4 | c.2514+23C>T | Intron (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53927583; called by muse, mutect2, varscan2
- PPM1A | chr14:60246012 G>A | 5'Flank (SNP) | VAF 5/11 reads (45%) | catalogued as rs201065840; called by muse, varscan2
- PTGER3 | c.*24-12840C>T | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23927C>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as COSV101042720; called by muse, mutect2, varscan2
- SNRPD1 | c.*2G>A | 3'UTR (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100303342; called by muse, mutect2, varscan2
